Somatic mutation profile of tumor specimen TCGA-FD-A3B8-01A (aliquot TCGA-FD-A3B8-01A-31D-A20D-08) from TCGA case TCGA-FD-A3B8, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 56.3 years (20,555 days).
Specimen TCGA-FD-A3B8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01cfdb2b-9f03-4a13-885b-c11e5d29850e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3B8-10A (Blood Derived Normal), aliquot TCGA-FD-A3B8-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f786675-5310-47fc-b746-9321f3e0b223

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRM | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65755199; called by muse, mutect2
- ANK1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV55882768; called by muse, mutect2
- ATF6 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 9/282 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.194); catalogued as COSV63409541; called by muse, mutect2
- CPED1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772467238, COSV60010428; called by mutect2, varscan2
- DDX23 | c.1035G>C p.K345N | Missense Mutation (SNP) | VAF 11/283 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV57285631; called by muse, mutect2
- DNAH8 | c.5985C>G p.I1995M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV59472457; called by muse, mutect2, varscan2
- FAM161B | c.2044G>C p.E682Q (on ENST00000651776; = p.E619Q on NM_152445.3) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV54103815; called by muse, mutect2
- FCGR2A | c.815G>C p.R272T (on ENST00000271450 / NM_001136219.3; = p.R271T on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.258); catalogued as COSV54840261; called by muse, mutect2
- ITGA2B | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV52234505; called by muse, mutect2
- KCNB2 | c.2396G>C p.R799T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.026); catalogued as COSV73052281; called by muse, mutect2
- KIAA1217 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56821769; called by muse, mutect2
- LRFN5 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53246766; called by muse, mutect2, varscan2
- NAA35 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV64484059; called by muse, mutect2
- NEB | c.2598G>C p.K866N | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51420084, COSV51449487; called by muse, mutect2
- NFKBIA | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1295773885, COSV53754304; called by muse, mutect2
- PAPPA2 | c.3511G>C p.E1171Q | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62808393; called by muse, mutect2
- PCDHA1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); catalogued as COSV65376291; called by muse, mutect2
- PCF11 | c.1571C>G p.S524C | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.527); catalogued as COSV100018577, COSV53536556; called by muse, mutect2
- SIK2 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59255321; called by muse, mutect2
- ZXDB | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100885994; called by muse, mutect2
- UHRF1BP1L | c.1346C>G p.S449* | Nonsense Mutation (SNP) | VAF 5/104 reads (5%) | called by muse, mutect2
- ADAMTS12 | c.2709G>A p.E903= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV61274728; called by muse, mutect2, varscan2
- CAPN12 | c.1590C>A p.I530= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV53149368; called by muse, mutect2, varscan2
- FANCE | c.981G>T p.L327= | Silent (SNP) | VAF 14/238 reads (6%) | catalogued as COSV57690867; called by muse, mutect2
- RACK1 | c.327G>C p.L109= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV65174728, COSV65175401; called by muse, mutect2
- TBX4 | c.1200G>A p.E400= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV53609266; called by muse, mutect2
- RBCK1 | c.167+490C>G | Intron (SNP) | VAF 4/86 reads (5%) | catalogued as COSV62292666; called by muse, mutect2
